TCGA case TCGA-KD-A5QS — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Corpus uteri; Tissue source site: Mount Sinai School of Medicine. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f4852819-6c2d-45f7-8479-5e79f143c7b5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Dead; Days to death: 1,941 days (5.3 years).

Diagnoses (3)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C54.2; Tissue or organ of origin: Myometrium; Site of resection or biopsy: Myometrium; Classification of tumor: primary; Age at diagnosis: 55.9 years (20,410 days); Year of diagnosis: 2009; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Sites of involvement: Bone, NOS / Uterus.
   Pathology details: Consistent pathology review: Yes; Necrosis present: Yes.
   Pathology details: Measurement type: Pathologic; Tumor burden: 11.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 11.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Bone, NOS. Age at diagnosis: 56.8 years (20,761 days); Days to diagnosis: 351 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Bone, NOS. Age at diagnosis: 56.9 years (20,769 days); Days to diagnosis: 359 days; Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.3; Tumor length measurement: 3; Tumor width measurement: 1.6.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 2.8; Tumor length measurement: 4.6; Tumor width measurement: 2.7.

Follow-up (4 entries)
- Day 351 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 351 days.
- Day 359 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 359 days.
- Days to follow up: 1,106 days (3.0 years); Disease response: With Tumor.
- Days to follow up: 1,941 days (5.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 61.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KD-A5QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 60 mg.
  Slide TCGA-KD-A5QS-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-KD-A5QS-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-KD-A5QS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Tumor total necrosis: Extensive Necrosis (>50%); Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Bone.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 30; Days from index date to pharmaceutical treatment ended: 72; Pharmaceutical therapy drug name: Taxotere; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 30; Days from index date to pharmaceutical treatment ended: 72; Pharmaceutical therapy drug name: Gemzar; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.
- Drug treatment 2, Therapy types: Pharmaceutical therapy type: Hormone Therapy.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 366; Days from index date to pharmaceutical treatment ended: 876; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.
- Drug treatment 4: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 366; Days from index date to pharmaceutical treatment ended: 471; Pharmaceutical therapy drug name: Doxorubicin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.
- Drug treatment 5: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 499; Days from index date to pharmaceutical treatment ended: 876; Pharmaceutical therapy drug name: Gemzar; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,941 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,941 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 351 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-KD-A5QS-01A-11D-A27O-01): tumor purity 0.81, ploidy 3.04, whole-genome doublings 1.
